Somatic mutation profile of tumor specimen 0DE7FV from CCDI case PBBPPW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.4 years (3,081 days).
Specimen 0DE7FV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d9b609d-eb35-4c4d-ac76-abe9fdf90b03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8da75ac-3d9d-43a1-ad88-c7a61fc6e997

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Frame Shift Ins 1, Silent 1, RNA 1, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3 | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 170/415 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766656069, COSV55576483; called by muse, mutect2, varscan2
- PTPRF | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.999); catalogued as rs775486548; called by muse, mutect2, varscan2
- SPATC1L | c.649C>T p.R217W (on ENST00000291672 / NM_001142854.2; = p.R63W on NM_032261.5) | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775580707, COSV52433319; called by muse, mutect2
- AATK | c.1887G>A p.W629* (on ENST00000326724 / NM_001080395.3; = p.W526* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 19/283 reads (7%) | called by muse, mutect2
- COL4A1 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRY1 | c.913C>G p.R305G | Missense Mutation (SNP) | VAF 128/463 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DTNBP1 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.864); called by muse, mutect2
- H2AC6 | c.95_99dup p.L34Tfs*25 | Frame Shift Ins (INS) | VAF 38/261 reads (15%) | called by mutect2, varscan2
- HMCN2 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OBSCN | c.23099C>T p.A7700V | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PKHD1L1 | c.10406G>C p.G3469A | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TUBB4A | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- FAM135A | c.1131C>T p.T377= (on ENST00000370479 / NM_001351599.1; = p.T360= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/261 reads (11%) | catalogued as rs1442010751, COSV52054472; called by muse, mutect2, varscan2
- GIPR | c.*1G>A | 3'UTR (SNP) | VAF 17/238 reads (7%) | called by muse, mutect2
- LILRB1 | c.1800+81C>T | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as rs1337167157; called by muse, mutect2, varscan2
- MED13 | c.1009+97C>A | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- RIOK1 | c.1097-65A>G | Intron (SNP) | VAF 30/113 reads (27%) | catalogued as rs563130883; called by muse, mutect2, varscan2
- SSPOP | n.8728G>A | RNA (SNP) | VAF 105/247 reads (43%) | catalogued as rs780497274, COSV100947046; called by muse, mutect2, varscan2
- TPM4 | c.-3G>T | 5'UTR (SNP) | VAF 92/531 reads (17%) | called by muse, mutect2, varscan2
